Somatic mutation profile of tumor specimen TCGA-IQ-A61O-01A (aliquot TCGA-IQ-A61O-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61O, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, spindle cell; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 43.6 years (15,920 days).
Specimen TCGA-IQ-A61O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c63eb9b3-0692-460d-9a51-9f9ad4ca968a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61O-10A (Blood Derived Normal), aliquot TCGA-IQ-A61O-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa816a29-25c6-422e-b981-2703031759b9

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 21, Silent 13, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99233528; called by muse, mutect2, varscan2
- ABCC12 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs199509150; called by muse, mutect2, varscan2
- C14orf39 | c.1364G>T p.R455I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV58781496, COSV58781699; called by muse, mutect2, varscan2
- CATSPER1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs543744984, COSV56408716; called by muse, mutect2, varscan2
- CCDC88B | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV100105990; called by muse, mutect2
- DEPDC1B | c.315-1G>A p.X105_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV99409918; called by muse, mutect2, varscan2
- DUSP1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV99496068; called by muse, mutect2
- E2F5 | c.454T>G p.L152V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99809788; called by muse, mutect2, varscan2
- FAM47B | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs767477342, COSV61452830, COSV61454653; called by muse, mutect2, varscan2
- GUCY1B1 | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV100025969, COSV52374949; called by muse, mutect2, varscan2
- ITGA7 | c.3394C>T p.R1132* (on ENST00000555728; = p.R1088* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as rs372423716, COSV99144135; called by muse, mutect2, varscan2
- KIDINS220 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286682721, COSV56753178, COSV99875851; called by muse, mutect2
- KIF5A | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673636; called by muse, mutect2, varscan2
- KRI1 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs144833930, COSV57265290; called by muse, mutect2, varscan2
- MYLK3 | c.168C>A p.D56E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV101189229; called by muse, mutect2, varscan2
- NDUFAF6 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs766120751, COSV54410941; called by muse, mutect2, varscan2
- NF1 | c.657A>G p.A219= | Splice Region (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100648386; called by muse, mutect2, varscan2
- NFASC | c.2119G>A p.E707K (on ENST00000339876 / NM_001378329.1; = p.E703K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs374212129; called by muse, mutect2, varscan2
- PCDH10 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1338502775, COSV52104594; called by muse, mutect2
- PCDHGA3 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV99547920; called by muse, mutect2, varscan2
- SCN7A | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs766963704, COSV69269732; called by muse, mutect2, varscan2
- UBQLN3 | c.1109G>A p.S370N | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61164881, COSV61166242; called by muse, mutect2, varscan2
- USH2A | c.6034A>C p.T2012P | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV100243219, COSV56417549; called by muse, mutect2, varscan2
- ZIK1 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV56737451; called by muse, mutect2, varscan2
- APOBEC3G | c.504_505del p.E170Afs*3 | Frame Shift Del (DEL) | VAF 40/181 reads (22%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.259_270del p.L87_K90del | In Frame Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- OSBPL10 | c.1753del p.E585Rfs*40 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- ADAMTSL3 | c.4527G>T p.T1509= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99721431; called by muse, mutect2, varscan2
- CDC42EP2 | c.81G>A p.S27= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs141215100; called by muse, mutect2, varscan2
- COL4A4 | c.2241C>T p.P747= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs374510402; called by muse, mutect2, varscan2
- FBLL1 | c.681G>A p.E227= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100606219; called by muse, mutect2, varscan2
- FZD10 | c.1113C>T p.V371= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99969635; called by muse, mutect2
- GPR32 | c.180C>A p.G60= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99567408; called by muse, mutect2, varscan2
- SLC6A12 | c.336C>T p.C112= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs545188353, COSV100675230; called by muse, mutect2, varscan2
- TAS2R40 | c.99C>T p.I33= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV101283031; called by muse, mutect2, varscan2
- TKFC | c.393G>A p.P131= | Silent (SNP) | VAF 25/154 reads (16%) | catalogued as rs779671347, COSV67523991; called by muse, mutect2, varscan2
- TMEM132D | c.1974G>T p.V658= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV101243112; called by muse, mutect2, varscan2
- VAV2 | c.783C>T p.S261= (on ENST00000371850 / NM_001134398.2; = p.S256= on NM_003371.4) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs765426332, COSV100896266; called by muse, mutect2, varscan2
- WNT1 | c.333C>T p.H111= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99525366; called by muse, mutect2
- XAB2 | c.2214C>T p.V738= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99352096; called by muse, mutect2, varscan2
